Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A1AV, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A1AV-01A (Primary Tumor).

1CS-0-3

Carcinoma, infiltrating duct, NOS 8500/3

Site code: breast, NOS C50.9

12/21/10 JW

Final Diagnosis

Breast, left, modified radical mastectomy: Infiltrating ductal carcinoma, Nottingham grade II (of III) [tubules 3/3, nuclei 2/3, mitoses 2/3; Nottingham score 7/9], forming a mass (2.8 x 2.3 x 2.1 cm) located in the retroareolar region of the breast. Ductal carcinoma in situ is absent. Angiolymphatic invasion is absent. Calcifications are not seen. The tumor involves the overlying skin [AJCC pT4]. All surgical resection margins, including the skin and deep margins, are negative for tumor (minimum tumor free margin, 1.1 cm, anterior superior margin). A single (of 23) left axillary mid/low lymph node is positive for metastatic carcinoma. The positive lymph node (1.7 cm in greatest dimension) shows extranodal extension.

Lymph nodes, left high axillary, excision: Multiple (2) left high axillary lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file 53a2ea2b-dd75-4f21-b31a-8bdbe4b40b26 (TCGA-AR-A1AV.5AD5B38F-5CC1-4A2F-96E6-F344D8FE0149.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).